Somatic mutation profile of tumor specimen MP2PRT-PARXCJ-TMP1-A (aliquot MP2PRT-PARXCJ-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PARXCJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,546 days).
Specimen MP2PRT-PARXCJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71e02149-8f88-4470-ada7-8e253d291380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXCJ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXCJ-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05557ae2-d8cf-4ce1-8995-1e20ded90d22

The open-access MAF lists 98 somatic variants for this specimen: 61 protein-altering or splice-affecting, 29 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 29, Nonsense Mutation 4, 5'Flank 2, RNA 2, Intron 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 57/410 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 31/470 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs965180023; called by muse, mutect2
- ADH5 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1477230237; called by muse, mutect2
- AKAP6 | c.5572G>C p.E1858Q | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55214489; called by muse, mutect2
- BRI3BP | c.655A>G p.S219G | Missense Mutation (SNP) | VAF 172/522 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV58296669; called by muse, varscan2
- CCDC171 | c.2139C>G p.F713L | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52639583, COSV52643745; called by muse, mutect2, varscan2
- COL8A2 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 60/835 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100291191; called by muse, mutect2
- DCAF8L1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1274514972, COSV71595516; called by muse, mutect2, varscan2
- DNAH6 | c.2023G>C p.D675H | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99031360; called by muse, mutect2, varscan2
- EIF4B | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV50405642; called by muse, mutect2, varscan2
- EML6 | c.4549G>A p.D1517N | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1388252823; called by muse, mutect2, varscan2
- FBXO2 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.213); catalogued as rs1209434284; called by muse, mutect2, varscan2
- FMN2 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201396397, COSV60419928; called by muse, varscan2
- LENG8 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 18/630 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as rs1275254985, COSV58726723; called by muse, mutect2
- MAP1A | c.6694C>T p.Q2232* | Nonsense Mutation (SNP) | VAF 23/691 reads (3%) | catalogued as COSV55811133; called by muse, mutect2
- NPR1 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1235250003, COSV64117855, COSV64118280; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXPE4 | c.1214C>G p.S405* (on ENST00000375478 / NM_001077639.2; = p.S121* on NM_017678.3) | Nonsense Mutation (SNP) | VAF 18/464 reads (4%) | catalogued as rs1285941296; called by muse, mutect2
- PDE1C | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 31/469 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100373130; called by muse, mutect2
- PDP1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 40/400 reads (10%) | catalogued as COSV52602978; called by muse, mutect2
- PPARGC1A | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 55/455 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV99337669; called by muse, mutect2, varscan2
- RIMS1 | c.3367G>C p.D1123H | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV53444432; called by muse, mutect2
- SARM1 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 63/839 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV50229371; called by muse, mutect2
- SYNE1 | c.3499G>A p.V1167I (on ENST00000367255 / NM_182961.4; = p.V1174I on NM_033071.3) | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs142734877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV60507342; called by muse, mutect2
- TCF7L2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs761411124; called by muse, mutect2
- TFAP2B | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53830560; called by muse, mutect2
- TTC12 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV59098420; called by muse, mutect2
- TUSC3 | c.738G>C p.Q246H | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs756069881; called by muse, mutect2
- ZNF487 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as rs1424943770; called by muse, mutect2, varscan2
- A1CF | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, varscan2
- ADAMTS6 | c.3170T>C p.L1057P | Missense Mutation (SNP) | VAF 138/491 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP6 | c.3979G>A p.D1327N | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANTXRL | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- ARMH4 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN3 | c.1695G>T p.Q565H | Missense Mutation (SNP) | VAF 132/374 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DDX56 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 21/698 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- DST | c.18675G>T p.L6225F (on ENST00000361203 / NM_001374722.1; = p.L3922F on NM_015548.5) | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELMOD1 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- FAM160B2 | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 57/534 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM169A | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); called by muse, mutect2
- FIGN | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- GAREM1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 55/477 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIN1 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJD4 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 78/908 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406870 ATTCAC>GG | Missense Mutation (DEL) | VAF 32/168 reads (19%) | called by pindel, varscan2*
- KBTBD11 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 199/999 reads (20%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED24 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NRXN1 | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- OR52E8 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 13/422 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPN13 | c.2393G>A p.C798Y | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, varscan2
- PTPRZ1 | c.6667G>C p.D2223H | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFWD3 | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 27/496 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2
- SMARCD1 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPEM2 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 34/865 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.114); called by muse, mutect2
- TRIM21 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, mutect2
- TRIM66 | c.3269T>C p.I1090T | Missense Mutation (SNP) | VAF 138/484 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTLL2 | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIM2 | c.1032G>C p.R344S | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF730 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZNF83 | c.1409C>G p.S470* | Nonsense Mutation (SNP) | VAF 56/523 reads (11%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1869G>A p.R623= | Silent (SNP) | VAF 34/447 reads (8%) | called by muse, mutect2
- BTBD17 | c.624G>C p.V208= | Silent (SNP) | VAF 59/1016 reads (6%) | called by muse, mutect2
- CA2 | c.633C>T p.L211= | Silent (SNP) | VAF 35/320 reads (11%) | called by muse, mutect2, varscan2
- CCDC138 | c.1083C>T p.F361= | Silent (SNP) | VAF 30/293 reads (10%) | catalogued as rs1170398745; called by muse, mutect2
- CCDC180 | c.1170C>T p.H390= | Silent (SNP) | VAF 90/352 reads (26%) | catalogued as rs775549438; called by muse, mutect2, varscan2
- CHSY3 | c.282G>A p.G94= | Silent (SNP) | VAF 163/863 reads (19%) | called by muse, mutect2, varscan2
- CR1L | c.1452G>C p.G484= | Silent (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
- DEF8 | c.1485C>A p.L495= | Silent (SNP) | VAF 36/410 reads (9%) | called by muse, mutect2
- DZIP3 | c.1188G>T p.L396= | Silent (SNP) | VAF 20/155 reads (13%) | called by mutect2, varscan2
- EPB41 | c.159G>A p.L53= | Silent (SNP) | VAF 93/453 reads (21%) | called by muse, mutect2, varscan2
- GABRA6 | c.888A>G p.K296= | Silent (SNP) | VAF 140/454 reads (31%) | catalogued as rs1484758589, COSV99195180; called by muse, mutect2, varscan2
- GDI1 | c.519G>A p.R173= | Silent (SNP) | VAF 111/337 reads (33%) | called by muse, mutect2, varscan2
- KCNN3 | c.519C>T p.I173= | Silent (SNP) | VAF 130/659 reads (20%) | called by muse, mutect2, varscan2
- LRRN1 | c.1590C>T p.Y530= | Silent (SNP) | VAF 110/445 reads (25%) | catalogued as rs754037453, COSV60012455; called by muse, mutect2, varscan2
- MCM7 | c.819C>A p.V273= | Silent (SNP) | VAF 54/505 reads (11%) | called by muse, mutect2, varscan2
- MYH7 | c.4374G>A p.Q1458= | Silent (SNP) | VAF 13/441 reads (3%) | called by muse, mutect2
- NBPF14 | c.8583A>G p.E2861= | Silent (SNP) | VAF 59/386 reads (15%) | called by muse, mutect2, varscan2
- OR4F15 | c.51C>T p.L17= | Silent (SNP) | VAF 42/472 reads (9%) | called by muse, mutect2
- OR4F17 | c.405C>T p.V135= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1206328655; called by mutect2, varscan2
- PDE3A | c.1185G>A p.V395= | Silent (SNP) | VAF 30/531 reads (6%) | called by muse, mutect2
- PHACTR1 | c.1635C>T p.L545= | Silent (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- PTPRG | c.906G>A p.L302= | Silent (SNP) | VAF 65/486 reads (13%) | called by muse, mutect2, varscan2
- PYGL | c.1293G>C p.L431= | Silent (SNP) | VAF 24/489 reads (5%) | called by muse, mutect2
- RXFP3 | c.111G>A p.T37= | Silent (SNP) | VAF 136/707 reads (19%) | catalogued as COSV100347146, COSV57504436; called by muse, mutect2, varscan2
- SIN3A | c.642T>C p.H214= | Silent (SNP) | VAF 194/608 reads (32%) | called by muse, mutect2, varscan2
- SLC4A2 | c.2370G>A p.L790= | Silent (SNP) | VAF 54/345 reads (16%) | called by muse, mutect2, varscan2
- SNX20 | c.654C>G p.L218= | Silent (SNP) | VAF 309/988 reads (31%) | called by muse, mutect2, varscan2
- UBE2O | c.1872G>A p.L624= | Silent (SNP) | VAF 17/397 reads (4%) | catalogued as COSV60063721; called by muse, mutect2
- UNC5B | c.2517C>G p.L839= | Silent (SNP) | VAF 41/377 reads (11%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-3476G>A | Intron (SNP) | VAF 68/553 reads (12%) | catalogued as rs1271278698; called by muse, mutect2, varscan2
- C2orf16 | chr2:27575319 G>C | 5'Flank (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2, varscan2
- COL6A5 | c.-249C>T | 5'UTR (SNP) | VAF 56/566 reads (10%) | catalogued as rs563329131; called by muse, mutect2
- DCHS2 | n.6510G>C | RNA (SNP) | VAF 44/394 reads (11%) | called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins CCTC | 3'Flank (INS) | VAF 20/76 reads (26%) | called by pindel, varscan2
- LINC00963 | chr9:129488793 C>T | 5'Flank (SNP) | VAF 63/617 reads (10%) | called by muse, mutect2, varscan2
- LINC01436 | n.227G>C | RNA (SNP) | VAF 30/546 reads (5%) | called by muse, mutect2
- UNC79 | c.3754+1524G>A | Intron (SNP) | VAF 43/467 reads (9%) | called by muse, mutect2
